Somatic mutation profile of tumor specimen BA2620D (aliquot aq-BA2620D) from BEATAML1.0 case 2150, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.5 years (23,922 days).
Specimen BA2620D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 658a3b6f-0252-4cca-bfd6-74ae0a30cf88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2127D (Solid Tissue Normal), aliquot aq-BA2127D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe115750-5084-4ea0-a03d-56777c0f8972

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, 5'UTR 1, Splice Site 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP7 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1198614474, COSV53017081; called by muse, mutect2, varscan2
- CDK8 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1160704856, COSV67421579; called by mutect2, varscan2
- CHRNB2 | c.1338+1G>A p.X446_splice | Splice Site (SNP) | VAF 35/86 reads (41%) | catalogued as rs1331721228, COSV63808898; called by muse, mutect2, varscan2
- GOLGA6L1 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1195135377; called by muse, varscan2
- LAMA4 | c.5269C>A p.P1757T (on ENST00000230538 / NM_001105206.3; = p.P1750T on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/363 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782001026; called by muse, mutect2, varscan2
- NBPF11 | c.1796T>C p.I599T | Missense Mutation (SNP) | VAF 108/352 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as rs1316245349; called by muse, mutect2, varscan2
- PUF60 | c.618C>A p.S206R (on ENST00000526683 / NM_001362896.2; = p.S189R on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs745447585, COSV57590962; called by muse, mutect2, varscan2
- DNER | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MPPED2 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SLC16A8 | c.99C>A p.Y33* | Nonsense Mutation (SNP) | VAF 60/139 reads (43%) | called by muse, mutect2, varscan2
- SLC7A7 | c.1528T>C p.S510P | Missense Mutation (SNP) | VAF 125/328 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SPARCL1 | c.1735A>G p.R579G | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- TOPAZ1 | c.3149C>T p.T1050I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, varscan2
- MYO7B | c.1437G>A p.S479= | Silent (SNP) | VAF 66/149 reads (44%) | catalogued as rs200853784; called by muse, mutect2, varscan2
- SLC25A31 | c.603C>T p.A201= | Silent (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- BTG4 | c.510+108G>T | Intron (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- TMEM61 | c.-33C>A | 5'UTR (SNP) | VAF 4/18 reads (22%) | catalogued as rs1381680641; called by muse, mutect2
